Somatic mutation profile of tumor specimen BA2074D (aliquot aq-BA2074D) from BEATAML1.0 case 2149, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 27.6 years (10,066 days).
Specimen BA2074D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7d8b132-06ca-4240-9794-9b71f8a2703e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2204D (Solid Tissue Normal), aliquot aq-BA2204D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83312bf8-a305-40b2-8001-4177152d7b8e

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, Frame Shift Ins 4, Nonsense Mutation 2, Splice Region 1, Frame Shift Del 1, Intron 1, Splice Site 1, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 20/55 reads (36%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ASAP1 | c.3247G>A p.D1083N | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.321); catalogued as rs1275826175; called by muse, mutect2, varscan2
- BPIFC | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs376981555; called by muse, mutect2, varscan2
- BRDT | c.2608G>T p.G870* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV100746456; called by muse, mutect2
- DFFA | c.783+7G>A | Splice Region (SNP) | VAF 39/88 reads (44%) | catalogued as rs772455668; called by muse, varscan2
- ERBIN | c.2191C>G p.P731A | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs760006813; called by muse, mutect2, varscan2
- GOLGA6L10 | c.809G>A p.R270K | Missense Mutation (SNP) | VAF 58/354 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0.316); catalogued as rs1220506694; called by muse, varscan2
- GOLGA8T | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs1299151609; called by muse, mutect2, varscan2
- GRIP1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs367635870; called by muse, mutect2
- JAM2 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs200218663, COSV57256777; called by muse, mutect2, varscan2
- MMEL1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.215); catalogued as rs927596248; called by muse, mutect2, varscan2
- NF1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as CM110507, CM1311446, COSV62212863; called by muse, mutect2, varscan2
- PTPN11 | c.853T>A p.F285I | Missense Mutation (SNP) | VAF 131/314 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as CM024733, CM086896, COSV61010689; called by muse, mutect2, varscan2
- SPTBN5 | c.8014G>A p.G2672R | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs756778746; called by muse, varscan2
- WT1 | c.1304-2A>G p.X435_splice | Splice Site (SNP) | VAF 121/290 reads (42%) | catalogued as COSV60078533; called by muse, mutect2, varscan2
- CPS1 | c.3940del p.S1314Pfs*5 | Frame Shift Del (DEL) | VAF 54/167 reads (32%) | called by mutect2, pindel, varscan2
- CTNND2 | c.3146G>T p.R1049M | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DPP6 | c.122C>A p.A41D | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUOX1 | c.2627_2628insTAGTT p.I877Sfs*6 | Frame Shift Ins (INS) | VAF 26/148 reads (18%) | called by mutect2, pindel, varscan2
- GDF10 | c.633G>C p.K211N | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2
- NF1 | c.1478T>C p.L493P | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFIC | c.1367dup p.A457Cfs*85 (on ENST00000443272 / NM_001245002.2; = p.A448Cfs*85 on NM_205843.3) | Frame Shift Ins (INS) | VAF 12/44 reads (27%) | called by mutect2, varscan2
- PCDH1 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 44/159 reads (28%) | called by muse, mutect2, varscan2
- PRR7 | c.768C>G p.H256Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- RAD21 | c.1416dup p.P473Tfs*5 | Frame Shift Ins (INS) | VAF 44/140 reads (31%) | called by mutect2, pindel, varscan2
- ZNF614 | c.19T>G p.S7A | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- ADAMTS8 | c.2535T>C p.S845= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- APBA2 | c.1101C>T p.I367= | Silent (SNP) | VAF 92/409 reads (22%) | catalogued as rs770286407; called by muse, mutect2, varscan2
- CFAP54 | c.1171C>A p.R391= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- RAX | c.900G>A p.P300= | Silent (SNP) | VAF 21/89 reads (24%) | called by muse, mutect2, varscan2
- SLC6A18 | c.1734C>T p.P578= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs750730505, COSV99722209; called by muse, mutect2, varscan2
- TAZ | c.306C>T p.I102= | Silent (SNP) | VAF 24/184 reads (13%) | called by muse, mutect2, varscan2
- VAMP2 | c.192C>T p.D64= | Silent (SNP) | VAF 56/154 reads (36%) | catalogued as rs750996677; called by muse, mutect2, varscan2
- CADM2 | c.62-75546G>A | Intron (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- PLIN1 | c.*655G>A | 3'UTR (SNP) | VAF 26/85 reads (31%) | called by muse, mutect2, varscan2
